Surgical pathology report (de-identified scan), TCGA case TCGA-FI-A2F8, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Washington University, specimen TCGA-FI-A2F8-01A (Primary Tumor).

[page 1 of 5]
Surgical Pathology Report

Final

1CD-0-3

adenocarcinoma, serous, NOS

8441/3

Site: Endometrium C54.1

for 6/10/11

SURGICAL PATHOLOGY REPORT FINAL WITH ADDENDUM

Service: Gynecology

Patient Type

Reported

DIAGNOSIS:

A. UTERUS, CERVIX, BILATERAL TUBES AND OVARIES, TOTAL ABDOMINAL HYSTERECTOMY, BILATERAL SALPINGO-OOPHORECTOMY:

UTERUS:

- INVASIVE HIGH GRADE SEROUS CARCINOMA OF THE ENDOMETRIUM
- TUMOR INVADES THE MYOMETRIUM TO A THICKNESS OF 5 MM, WHERE THE TOTAL MYOMETRIAL THICKNESS IS 19 MM
- FOCAL LYMPHOVASCULAR SPACE INVASION IDENTIFIED
- CARCINOMA INVOLVES AN ENDOMETRIAL POLYP
- INACTIVE ENDOMETRIUM
- TUMOR INVADES CERVICAL EPITHELIUM AND STROMA
- ADENOMYOSIS
- LEIOMYOMATA (LARGEST 1.4 CM)
- SEE SYNOPTICS

OVARIES, RIGHT AND LEFT

- EPITHELIAL INCLUSION CYSTS
- NO CARCINOMA IDENTIFIED

FALLOPIAN TUBES, RIGHT AND LEFT

- NO CARCINOMA IDENTIFIED

B. LYMPH NODES, LEFT EXTERNAL ILIAC, EXCISION

- NO CARCINOMA IDENTIFIED IN THREE LYMPH NODES (0/3)

C. LYMPH NODES, RIGHT EXTERNAL ILIAC, EXCISION

- NO CARCINOMA IDENTIFIED IN THREE LYMPH NODES (0/3)

D. LYMPH NODES, LEFT OBTURATOR, EXCISION

- NO CARCINOMA IDENTIFIED IN FIVE LYMPH NODES (0/5)

E. LYMPH NODES, LEFT COMMON ILIAC/PERIAORTIC, EXCISION

- NO CARCINOMA IDENTIFIED IN FOUR LYMPH NODES (0/4)

F. LYMPH NODES, RIGHT OBTURATOR, EXCISION

[page 2 of 5]
- NO CARCINOMA IDENTIFIED IN THIRTEEN LYMPH NODES (0/13)
- G. LYMPH NODES, RIGHT COMMON ILIAC/PERIAORTIC, EXCISION
- NO CARCINOMA IDENTIFIED IN TWO LYMPH NODES (0/2)
- H. PERITONEUM, RIGHT GUTTER, BIOPSY
- NO CARCINOMA IDENTIFIED
- I. PERITONEUM, LEFT PELVIC SIDEWALL, BIOPSY
- NO CARCINOMA IDENTIFIED
- J. PERITONEUM, RIGHT PELVIC SIDEWALL, BIOPSY
- NO CARCINOMA IDENTIFIED
- K. PERITONEUM, LEFT GUTTER, BIOPSY
- NO CARCINOMA IDENTIFIED
- L. PERITONEUM, CUL-DE-SAC, BIOPSY
- NO CARCINOMA IDENTIFIED
- M. OMENTUM, BIOPSY
- NO CARCINOMA IDENTIFIED

Intraoperative Consultation:

An intraoperative non-microscopic consultation was obtained and interpreted as: "Called to pick up a uterus, cervix, bilateral tubes and ovaries," consisting of a 104.5 gram, 8.5 x 5 x 2.5 cm uterus. Opened to show an exophytic friable mass associated with an endometrial polyp and the posterior endometrium. Tumor and normal tissue collected for . Rest for permanents," by

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis.

History:

The patient is a /year old woman with newly diagnosed endometrial high grade serous carcinoma
Operative procedure: Total abdominal hysterectomy, bilateral salpingo-oophorectomy, pelvic and periaortic lymph node dissection, peritoneal biopsies, and omental biopsy.

Specimen(s) Received:

- A: UTERUS, CERVIX, BILATERAL OVARIES AND FALLOPIAN TUBES
- B: LYMPH NODES, LEFT EXTERNAL ILIAC
- C: LYMPH NODES, RIGHT EXTERNAL ILIAC
- D: LYMPH NODES, LEFT OBTURATOR
- E: LYMPH NODES, LEFT COMMON ILIAC/PERIAORTIC
- F: LYMPH NODES, RIGHT OBTURATOR

[page 3 of 5]
G. LYMPH NODES, RIGHT COMMON ILIAC/PERIAORTIC
H. RIGHT GUTTER
I. LEFT PELVIC SIDE WALL
J. RIGHT PELVIC SIDE WALL
K. LEFT GUTTER
L. CUL DE SAC PERITONEUM
M. OMENTUM

Gross Description:

The specimens are received in 13 containers of formalin, each labeled "Jar 1". The first container is labeled "1". It holds a 104.5 gram specimen including an 8.5 x 5 x 3.5 cm previously opened uterus and cervix, and uterine tubes and ovaries, as described in the intraoperative non-microscopic consultation. The purple-tan uterine serosa is smooth, but is distorted by multiple subserosal fibroids. The 3.5 cm endocervix is covered by shiny pink mucosa, with multiple hemorrhagic foci. The external cervical os is unremarkable. The 2.4 cm long x 0.9 cm wide endocervical canal is lined by shiny light tan mucosa, with areas of irregular, slightly thickened mucosa, consistent with tumor. Sections of the posterior cervix show a 2 cm diameter white tumor that invades to a depth of 0.9 cm. Sections of the anterior cervix also show apparent tumor involvement, involving a 2.2 cm long portion of the endocervical canal and extending to a depth of 0.6 cm. There is a 4 x 2.5 x 1.5 cm mass in the endometrial cavity, at the right/posterior uterine fundus. The most inferior 2 cm of this mass is polypoid. The superior portion of the mass is exophytic. Sections of the mass and underlying myometrium show the mass invades the myometrium to a depth of 0.9 cm, where the total endomyometrial thickness is 2.2 cm. Sections of the myometrium show multiple intramural and subserosal fibroids, measuring up to 1.4 cm in diameter. The fibroids are firm, white, with a whorled cut surface. The largest fibroid is in the posterior/left fundal portion of the myometrium, and is slightly softened. The 2 x 1.4 x 1.1 cm light tan right ovary has a cerebriform surface. Sections show heterogeneous tan and white ovarian parenchyma, without masses. The 5.2 cm long x 0.6 cm diameter right fallopian tube has a smooth surface, and an unremarkable fimbriated end. Sections show a pinpoint lumen, and no masses. The 1.9 x 1.8 x 1 cm light tan left ovary has a cerebriform surface. Sections show heterogeneous tan and white ovarian parenchyma, without masses. The 4.5 cm long x 0.5 cm diameter purple-tan left fallopian tube has a smooth surface and an unremarkable fimbriated end. Sections show a pinpoint lumen, and a 0.2 cm diameter tan nodule adjacent to the tube. Labeled A1 - anterior cervix; A2 - anterior lower uterine segment; A3 - posterior cervix; A4 - posterior lower uterine segment; A5 - anterior endomyometrium, with fibroid; A6 - posterior endomyometrium, with tumor; A7 - remainder of polypoid portion of tumor; A8 and A9 - posterior endomyometrium, with tumor; A10 - posterior endomyometrium, with largest, softened fibroid and smaller firm fibroid; A11 - right ovary and fallopian tube; A12 - left ovary and fallopian tube. Jar 2.

The second container is labeled "2". It holds several pieces of yellow-tan fibroadipose tissue, measuring 6.2 x 4.7 x 0.5 cm in aggregate. Sections show one 1.7 cm diameter tan lymph node, and a 0.8 cm diameter fatty replaced yellow-tan lymph node. Labeled B1 - one lymph node, sectioned; B2 - one lymph node and additional fibroadipose tissue; B3 and B4 - fibroadipose tissue. Jar 1.

The third container is labeled "3". It holds several pieces of yellow-tan fibroadipose tissue, measuring 5.8 x 4.2 x 0.3 cm in aggregate. Sections show a 0.7 cm diameter tan lymph node, and a 0.8 cm diameter tan lymph node. Labeled C1 - two lymph nodes, and additional fibroadipose tissue; C2 - fibroadipose tissue. Jar 1.

The fourth container is labeled "4". It holds several pieces of yellow-tan fibroadipose tissue, measuring 5.2 x 4 x 0.8 cm in aggregate. Sections show several tan lymph nodes and putative fatty-replaced yellow lymph nodes, measuring up to 1.6 cm in diameter. Labeled D1 and D2 - two bisected lymph nodes per cassette; D3 and D4 - putative lymph nodes. Jar 1.

The fifth container is labeled "5". It holds three pieces of yellow-tan fibroadipose tissue, that measure 3.8 x 3.5 x 0.8 cm in aggregate. Sections show several tan lymph nodes, measuring up to 1.4 cm in diameter. Labeled E1 - one bisected lymph node; E2 - lymph nodes. Jar 1.

The sixth container is labeled "6". It holds multiple pieces of yellow-tan fibroadipose tissue, measuring 6 x 5.2 x 0.6 cm in aggregate. Sections show several yellow-tan lymph nodes, measuring up to 3.7 cm in greatest dimension. Labeled F1 and F2 - one lymph node, bisected; F3 - two bisected lymph nodes; F4 - one bisected lymph node; F5 - two bisected lymph nodes; F6 and F7 - lymph nodes. Jar 1.

The seventh container is labeled "7". It holds three pieces of yellow-tan fibroadipose tissue, that measure 3 x 0.9 x 0.3 cm in aggregate. One piece of fibroadipose tissue contains a 0.7 cm

[page 4 of 5]
diameter tan lymph node. Labeled G1. Jar 0.

The eighth container is labeled " " It holds a 1.5 x 1.1 x 0.7 cm piece of tan peritoneum and yellow adipose tissue. The tan tissue is focally firm. Bisected. Labeled H1. Jar 1.

The ninth container is labeled " " It holds a 1.5 x 0.7 x 0.3 cm piece of tan-purple peritoneum and underlying yellow adipose tissue. Sectioned. Labeled J1. Jar 0.

The tenth container is labeled " " It holds a 1.5 x 0.6 x 0.2 cm piece of tan firm tissue. Bisected. Labeled J1. Jar 0.

The eleventh container is labeled " " It holds a 0.9 x 0.8 x 0.2 cm piece of tan translucent peritoneum and yellow adipose tissue. Sectioned. Labeled K1. Jar 0.

The twelfth container is labeled " " It holds a 1.8 x 0.7 x 0.2 cm piece of translucent tan peritoneum. Sectioned. Labeled L1. Jar 0.

The thirteenth container is labeled " " It holds two pieces of yellow-tan omentum, measuring 6.2 x 2.8 x 0.5 cm in aggregate. Sections show no masses. Labeled M1 to M3. Jar 0.

SYNOPTIC REPORTING FORM FOR MALIGNANT ENDOMETRIAL TUMORS

HISTOPATHOLOGIC TYPE

The histologic diagnosis is adenocarcinoma, serous papillary type

FIGO GRADE

High grade

TUMOR INVASION

Invasive tumor is present with superficial invasion into the luminal 1/3 of the myometrium

TUMOR SIZE

The tumor invades to a depth of 5 mm

The myometrial thickness is 19 mm

ENDOCERVICAL INVOLVEMENT

The endocervix is involved by serous carcinoma r in the mucosa and stroma

LYMPHOVASCULAR SPACE INVASION

Lymphovascular space invasion by tumor is present but limited in scope

REGIONAL LYMPH NODES (N)

The regional lymph nodes are free of tumor in 30 nodes

The total number of lymph nodes examined is 30

Extranodal extension by tumor is not applicable; no nodal metastases are present

DISTANT METASTASIS (M)

No distant metastasis reportedly present (M0)

PRIMARY TUMOR (TNM Category/FIGO Stage)

Tumor involves serosa and/or adnexa (direct extension or metastasis) and/or cancer cells in ascites or peritoneal washings (T3a/IIIA)

Peritoneal washings positive for adenocarcinoma

PATHOLOGIC STAGE GROUPING

The overall pathologic AJCC stage of the tumor is pT3a/N0/Mx

[page 5 of 5]
The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Addendum Comment

The tumor cells are positive for MLH1 (90% tumor cells positive), MSH-2 (95% tumor cells positive), MSH-6 (95-100% tumor cells positive) and PMS2 (95% tumor cells positive).

END OF REPORT

Page 5 of 5

Source: NCI Genomic Data Commons file 3c55252c-93be-4a51-bdec-15ca0d601739 (TCGA-FI-A2F8.9445945A-A7AC-4C36-889B-68A50644D556.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).